Somatic mutation profile of tumor specimen TCGA-44-3396-01A (aliquot TCGA-44-3396-01A-01D-1553-08) from TCGA case TCGA-44-3396, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.1 years (27,073 days).
Specimen TCGA-44-3396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42cc08c5-3e5b-415f-af35-0643fcb9329e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3396-10A (Blood Derived Normal), aliquot TCGA-44-3396-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed2b0997-51ad-44b3-b865-9872bbdfeaac

The open-access MAF lists 200 somatic variants for this specimen: 155 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 41, Nonsense Mutation 11, Frame Shift Ins 4, Frame Shift Del 3, Splice Site 3, Splice Region 2, Intron 2, RNA 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: likely pathogenic; called by muse, mutect2
- NIPBL | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 10/133 reads (8%) | catalogued as rs797045752, COSV56953286; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AACS | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99908097; called by muse, mutect2
- ADAMTS20 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs531290635, COSV101239486, COSV67131269; called by muse, mutect2, varscan2
- AKAP9 | c.4285G>A p.V1429I | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs371307390; called by muse, mutect2, varscan2
- AKR1C3 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101003109; called by muse, mutect2, varscan2
- ALPK2 | c.3859G>C p.E1287Q | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100864462, COSV64496191; called by muse, mutect2
- ANKRD17 | c.5587C>T p.H1863Y | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV100429385; called by muse, mutect2
- ANKRD7 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV54555235, COSV99501189; called by muse, mutect2, varscan2
- ARL15 | c.110G>C p.C37S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101544830; called by muse, mutect2, varscan2
- ASCC3 | c.6486G>C p.M2162I | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100976602; called by muse, mutect2
- ASPM | c.787A>C p.S263R | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV99660556; called by muse, mutect2, varscan2
- ATP5F1A | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.318); catalogued as rs146467617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BASP1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV59470313; called by muse, mutect2, varscan2
- BMT2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1562915812, COSV99774689, COSV99774775; called by muse, mutect2
- CBX7 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1303748384, COSV99334094; called by muse, mutect2
- CCR2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 46/407 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs372424162; called by muse, mutect2, varscan2
- CD300LB | c.6G>T p.W2C | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100075351, COSV100075466; called by muse, mutect2
- CDR1 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 30/238 reads (13%) | catalogued as COSV100983422, COSV65164429; called by muse, mutect2
- CELSR3 | c.9791C>T p.S3264L | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99373799; called by muse, mutect2, varscan2
- CENPF | c.6097C>G p.L2033V | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100871728; called by muse, mutect2
- CFAP161 | c.834G>T p.M278I | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99715500; called by muse, mutect2, varscan2
- CLASRP | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.07); catalogued as COSV99673888; called by muse, mutect2
- CLUL1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV100093779; called by muse, mutect2, varscan2
- CNR1 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as COSV100759244, COSV100759317; called by muse, mutect2
- COG1 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.218); catalogued as COSV100245339; called by muse, mutect2, varscan2
- COL4A4 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100307035; called by muse, mutect2
- COPS4 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100018598, COSV52316486; called by muse, mutect2, varscan2
- CPA4 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV55982452, COSV55983462, COSV99745101; called by muse, mutect2, varscan2
- CPNE4 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753178143, COSV70192655; called by muse, mutect2
- CUBN | c.4732G>T p.A1578S | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1229064818, COSV100912881; called by muse, mutect2, varscan2
- CWC15 | c.112C>G p.H38D | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54412451, COSV99688573; called by muse, mutect2, varscan2
- DAAM2 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.377); catalogued as COSV99225945; called by muse, mutect2
- DACH2 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs1198555244, COSV100913386; called by muse, mutect2, varscan2
- DGKD | c.1902G>C p.Q634H (on ENST00000264057 / NM_152879.3; = p.Q590H on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99896567; called by muse, mutect2, varscan2
- DGKE | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99400988; called by muse, mutect2, varscan2
- DHX15 | c.1790del p.P597Hfs*19 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV100391613; called by mutect2, pindel
- DNAH7 | c.10210A>G p.R3404G | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100415679; called by muse, mutect2
- DNAI1 | c.1654C>G p.H552D | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV99646903; called by muse, mutect2
- DROSHA | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100757649; called by muse, mutect2
- DST | c.18397G>C p.D6133H (on ENST00000361203 / NM_001374722.1; = p.D3830H on NM_015548.5) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99757261; called by muse, mutect2, varscan2
- DYNC2H1 | c.3095A>T p.Q1032L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100518776; called by muse, mutect2, varscan2
- ERICH3 | c.2571C>A p.D857E | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.083); catalogued as COSV100444670; called by muse, mutect2, varscan2
- EYA2 | c.855A>T p.L285F | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100426963; called by muse, mutect2
- FHDC1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752268371, COSV99471383; called by muse, mutect2, varscan2
- FOLH1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99923351; called by muse, mutect2
- FUT3 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99744680; called by muse, mutect2
- GALNT1 | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV99322238; called by muse, mutect2, varscan2
- GBP6 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as rs775196023, COSV100969566; called by muse, mutect2, varscan2
- GLG1 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.65); catalogued as COSV52664016, COSV99215873; called by muse, mutect2, varscan2
- GPR50 | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs200876781, COSV99506242; called by muse, mutect2, varscan2
- GRIA3 | c.1267C>G p.R423G | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV99990557; called by muse, mutect2, varscan2
- HIVEP2 | c.78G>C p.W26C | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99173825; called by muse, mutect2
- HOXA6 | c.209C>A p.A70E | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99762358; called by muse, mutect2, varscan2
- HRNR | c.2738C>A p.S913Y | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.795); catalogued as COSV100913573; called by muse, mutect2, varscan2
- IL36A | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs749638456, COSV52083307, COSV52083708; called by muse, mutect2
- INHBA | c.1235A>G p.K412R | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99637826; called by muse, mutect2, varscan2
- ITGAE | c.2251T>G p.C751G | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99561121; called by muse, mutect2, varscan2
- ITGAL | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs202150477; called by muse, mutect2, varscan2
- KALRN | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99565077; called by muse, varscan2
- KCTD4 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV61241455; called by muse, mutect2
- KIDINS220 | c.1342del p.A448Qfs*32 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as COSV56751991; called by mutect2, pindel, varscan2
- KIF17 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as rs761824033, COSV99929233; called by muse, mutect2, varscan2
- KMT2C | c.4777T>G p.S1593A | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100072823; called by muse, mutect2, varscan2
- KRT84 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1191231697, COSV99230912; called by muse, mutect2, varscan2
- L3HYPDH | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99904464; called by muse, mutect2
- LAMB2 | c.3619C>T p.R1207C | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs372032732; called by muse, mutect2, varscan2
- LEF1 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); catalogued as COSV99489691; called by muse, mutect2, varscan2
- LPP | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100447588; called by muse, mutect2, varscan2
- LRRK2 | c.2221G>T p.G741* | Nonsense Mutation (SNP) | VAF 23/184 reads (13%) | catalogued as COSV54143703; called by muse, mutect2, varscan2
- LRRK2 | c.4197G>T p.E1399D | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100110467; called by muse, mutect2, varscan2
- MAP3K4 | c.880A>T p.I294F | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100815458; called by muse, mutect2
- MED1 | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 45/163 reads (28%) | catalogued as COSV56128704; called by muse, mutect2, varscan2
- MED12L | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292367508, COSV56368602; called by muse, mutect2, varscan2
- MLANA | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV101199958; called by muse, mutect2
- MRPL16 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100276500; called by muse, mutect2, varscan2
- MTM1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1557415137, COSV60336381; called by muse, mutect2, varscan2
- MYO18B | c.7051T>A p.C2351S | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV59126057; called by muse, mutect2
- MYPN | c.479A>C p.E160A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100590082, COSV62736398; called by muse, mutect2, varscan2
- NFIB | c.686-1G>T p.X229_splice | Splice Site (SNP) | VAF 30/404 reads (7%) | catalogued as COSV101101338; called by muse, mutect2
- NIBAN3 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV99962346; called by muse, mutect2
- NIFK | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs185431138, COSV53534192, COSV99590654; called by muse, mutect2, varscan2
- NIN | c.56G>T p.S19I | Missense Mutation (SNP) | VAF 68/536 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99813850; called by muse, mutect2, varscan2
- NIP7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 60/544 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99650765; called by muse, mutect2, varscan2
- NPHP4 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100976974; called by muse, mutect2
- NXPH2 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs771139726, COSV55642517, COSV99740805; called by muse, mutect2, varscan2
- OR2C3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100825722; called by muse, mutect2, varscan2
- OR4A5 | c.253T>A p.C85S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs1471449087, COSV100157143; called by muse, mutect2
- OSBP | c.1340T>G p.L447R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99803056; called by muse, mutect2, varscan2
- PARP6 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV53005600, COSV99536121; called by muse, mutect2
- PCDHGC4 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs756658304, COSV99340594; called by muse, mutect2, varscan2
- PDYN | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99453092; called by muse, mutect2
- PGK1 | c.641+1G>C p.X214_splice | Splice Site (SNP) | VAF 23/192 reads (12%) | catalogued as COSV100965345, COSV100965366; called by muse, mutect2, varscan2
- PHF8 | c.1063C>T p.H355Y (on ENST00000357988 / NM_001184896.1; = p.H319Y on NM_015107.3) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.645); catalogued as COSV100154347; called by muse, mutect2, varscan2
- PIK3C3 | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1306170227, COSV56281334; called by muse, mutect2, varscan2
- PLA2R1 | c.2261G>C p.R754T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV99323014; called by muse, mutect2, varscan2
- PLBD1 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV99554591; called by muse, mutect2, varscan2
- PPM1D | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs770814597, COSV100010943; called by muse, mutect2, varscan2
- PPM1J | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV99588350; called by muse, mutect2, varscan2
- PPP1R15B | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100916344; called by muse, mutect2
- PUS3 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as rs575899270, COSV99916980; called by muse, mutect2, varscan2
- QTRT1 | c.809G>C p.C270S | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV99139060; called by muse, mutect2
- RIPOR2 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as rs1304622009, COSV52429087; called by muse, mutect2, varscan2
- RNF180 | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV99684760; called by muse, mutect2, varscan2
- RP1L1 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as COSV101223322, COSV66757657; called by muse, mutect2, varscan2
- SCAP | c.3141G>T p.G1047= | Splice Region (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99650694; called by muse, mutect2, varscan2
- SCAP | c.3088G>C p.D1030H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55545671, COSV99650696; called by muse, mutect2
- SCML1 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV101193889; called by muse, mutect2, varscan2
- SCNN1D | c.699C>A p.Y233* (on ENST00000338555; = p.Y397* on NM_001130413.4) | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100330029; called by muse, mutect2
- SERPINE2 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99296786; called by muse, mutect2
- SH3GL3 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776295437, COSV100196915; called by muse, mutect2, varscan2
- SHC1 | c.753C>T p.I251= (on ENST00000368445 / NM_183001.5; = p.I141= on NM_003029.5) | Splice Region (SNP) | VAF 21/369 reads (6%) | catalogued as COSV100821099; called by muse, mutect2
- SIGLEC14 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99707587; called by muse, mutect2, varscan2
- SLC25A53 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782046940, COSV100656023; called by muse, mutect2, varscan2
- SLC26A9 | c.1982C>G p.T661S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100536448; called by muse, mutect2, varscan2
- SLC39A11 | c.623-1G>C p.X208_splice (on ENST00000542342 / NM_001159770.2; = p.X201_splice on NM_139177.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/209 reads (11%) | catalogued as COSV99723264; called by muse, mutect2, varscan2
- SPAG16 | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV100435960; called by muse, mutect2
- SRCIN1 | c.3125C>T p.P1042L (on ENST00000621492; = p.P1008L on NM_025248.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1481931862; called by muse, mutect2
- ST6GALNAC3 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 22/163 reads (13%) | PolyPhen benign (0.076); catalogued as COSV100083776; called by muse, mutect2, varscan2
- TADA2B | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV99380666; called by muse, mutect2, varscan2
- TANC2 | c.5132A>G p.Y1711C | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV101267503; called by muse, mutect2, varscan2
- TAT | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs768158086, COSV100587654; called by muse, mutect2, varscan2
- THSD7A | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101448758; called by muse, mutect2
- TIGD2 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); catalogued as COSV100392384; called by muse, mutect2, varscan2
- TLR7 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV101027929; called by muse, mutect2, varscan2
- TMEM151A | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59174702; called by muse, mutect2, varscan2
- TNFRSF11A | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV99500292; called by muse, mutect2, varscan2
- TOP1 | c.1056C>G p.N352K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100793860; called by muse, mutect2, varscan2
- TPP1 | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751645191, COSV100196442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAPPC13 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99198912; called by muse, mutect2
- TRAPPC6B | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100351258; called by muse, mutect2, varscan2
- TSEN34 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99824875; called by muse, mutect2
- TTLL7 | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99552542; called by muse, mutect2, varscan2
- UGGT2 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs192124348, COSV100948732; called by muse, mutect2, varscan2
- UGT2B10 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | catalogued as COSV99608416; called by muse, mutect2
- UNC80 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV99779857; called by muse, mutect2, varscan2
- USF3 | c.5519C>G p.S1840* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | catalogued as COSV100325424; called by muse, mutect2
- USP48 | c.2476G>C p.D826H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as COSV100379957; called by muse, mutect2
- WDPCP | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99705616; called by muse, mutect2
- WDR59 | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 36/213 reads (17%) | catalogued as rs200814192, COSV50940094; called by muse, mutect2, varscan2
- ZCCHC12 | c.898A>G p.R300G | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV100038540; called by muse, mutect2, varscan2
- ZNF354C | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs754844304, COSV100203669; called by muse, mutect2
- ZNF41 | c.603C>A p.N201K | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57441772; called by muse, mutect2
- ZNF616 | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 16/143 reads (11%) | catalogued as COSV100348394; called by muse, mutect2, varscan2
- ZNF763 | c.46G>T p.E16* (on ENST00000358987 / NM_001367172.2; = p.E19* on NM_001012753.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/253 reads (10%) | catalogued as COSV100676144; called by muse, mutect2
- ATP2A1 | c.857dup p.S287Lfs*11 | Frame Shift Ins (INS) | VAF 22/197 reads (11%) | called by mutect2, pindel, varscan2
- CDH19 | c.592dup p.S198Ffs*3 | Frame Shift Ins (INS) | VAF 18/123 reads (15%) | called by mutect2, pindel, varscan2
- DOK1 | c.878del p.P293Qfs*8 | Frame Shift Del (DEL) | VAF 16/141 reads (11%) | called by mutect2, pindel, varscan2
- LRRC4 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 33/340 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.019); called by muse, mutect2
- MAP3K13 | c.1089G>T p.W363C | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR2A | c.2305A>G p.M769V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PSG1 | c.842C>G p.P281R | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.967); called by muse, mutect2
- RPRD1B | c.411dup p.K138Qfs*22 | Frame Shift Ins (INS) | VAF 21/157 reads (13%) | called by mutect2, pindel, varscan2
- VWC2 | c.824dup p.N275Kfs*21 | Frame Shift Ins (INS) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- ACMSD | c.336G>A p.V112= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV99299169; called by muse, mutect2
- ADPRM | c.912A>T p.P304= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs1380581636, COSV100541412; called by muse, mutect2, varscan2
- AKAP9 | c.6594A>G p.K2198= (on ENST00000359028; = p.K2174= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/245 reads (24%) | catalogued as COSV100662519; called by muse, mutect2, varscan2
- ARHGEF28 | c.444G>A p.E148= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99709295; called by muse, mutect2
- CFAP46 | c.294G>A p.S98= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs143120032; called by muse, mutect2, varscan2
- CNTN5 | c.2448T>C p.N816= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99678012; called by muse, mutect2, varscan2
- CRX | c.369G>A p.T123= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as rs368752695; called by muse, mutect2, varscan2
- DNAAF6 | c.417C>T p.C139= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as COSV100314524; called by muse, mutect2
- EPHA2 | c.1944G>A p.L648= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV64452961; called by muse, mutect2
- FARSA | c.1161C>T p.L387= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100108873; called by muse, mutect2, varscan2
- FER1L6 | c.3699G>A p.K1233= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV101205940; called by muse, mutect2, varscan2
- FLNB | c.813G>T p.V271= | Silent (SNP) | VAF 42/371 reads (11%) | catalogued as COSV99913572; called by muse, mutect2, varscan2
- GPR50 | c.1008C>A p.A336= | Silent (SNP) | VAF 34/292 reads (12%) | catalogued as COSV99506246; called by muse, mutect2, varscan2
- HAO1 | c.243C>A p.A81= | Silent (SNP) | VAF 18/211 reads (9%) | catalogued as COSV101113232; called by muse, mutect2
- JAKMIP1 | c.1803C>G p.L601= | Silent (SNP) | VAF 26/237 reads (11%) | catalogued as rs370646732, COSV51531255, COSV99289831; called by muse, mutect2, varscan2
- MAD2L2 | c.102C>A p.R34= | Silent (SNP) | VAF 30/330 reads (9%) | catalogued as COSV52416604, COSV99336017; called by muse, mutect2
- MIB2 | c.2958C>T p.S986= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs1357973696, COSV100598943; called by muse, mutect2, varscan2
- MOGS | c.831A>C p.V277= | Silent (SNP) | VAF 43/311 reads (14%) | catalogued as COSV99270584; called by muse, mutect2, varscan2
- MST1 | c.375C>T p.I125= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as rs896822394, COSV99610847; called by muse, mutect2, varscan2
- NLRC5 | c.2262C>T p.L754= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV52659214; called by muse, mutect2, varscan2
- NPHS1 | c.3426G>A p.L1142= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV62286296; called by muse, mutect2
- NUDT11 | c.240G>T p.L80= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV101047070; called by muse, mutect2
- OR5M8 | c.171C>A p.P57= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV100510693; called by muse, mutect2, varscan2
- PCDH15 | c.1780C>A p.R594= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1252259548, COSV100215594, COSV100222141, COSV57266343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDLIM4 | c.600C>A p.P200= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs754780133, COSV53805369, COSV53805403, COSV99516914; called by mutect2, varscan2
- PHKG2 | c.1119C>A p.L373= | Silent (SNP) | VAF 27/209 reads (13%) | catalogued as COSV100079621; called by muse, mutect2, varscan2
- POLG2 | c.486G>A p.L162= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as COSV56750712; called by muse, mutect2, varscan2
- PTPRD | c.1263G>C p.P421= | Silent (SNP) | VAF 24/248 reads (10%) | catalogued as COSV100645166, COSV61938702; called by muse, mutect2, varscan2
- PXN | c.1473C>T p.L491= (on ENST00000228307 / NM_001080855.3; = p.L457= on NM_002859.4) | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV57220475; called by muse, mutect2
- RCC2 | c.357A>T p.R119= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100965170; called by muse, mutect2, varscan2
- RETSAT | c.918G>A p.V306= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV99806079; called by muse, varscan2
- SEMA3A | c.922C>T p.L308= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV54883491, COSV99547000; called by muse, mutect2, varscan2
- SETD1A | c.456C>T p.V152= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as rs757785160, COSV99353182; called by muse, mutect2, varscan2
- SQOR | c.1248C>G p.L416= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV99525842; called by muse, mutect2, varscan2
- THSD7B | c.3534G>A p.L1178= (on ENST00000272643; = p.L1176= on NM_001316349.2) | Silent (SNP) | VAF 34/260 reads (13%) | catalogued as rs909609125, COSV99752606; called by muse, mutect2, varscan2
- TNKS1BP1 | c.18C>T p.L6= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs553347344, COSV53478240; called by muse, mutect2, varscan2
- TOMM20L | c.87C>G p.L29= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV62878362, COSV62878426; called by muse, mutect2, varscan2
- TSPEAR | c.108G>A p.A36= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs782589581, COSV59961184; called by muse, mutect2, varscan2
- TTC25 | c.543C>G p.L181= | Silent (SNP) | VAF 27/223 reads (12%) | catalogued as COSV101102995; called by muse, mutect2, varscan2
- VIRMA | c.4257C>T p.L1419= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs139309146; called by muse, mutect2
- ZNF182 | c.1707C>A p.P569= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV100527084; called by muse, mutect2, varscan2
- AC073310.1 | n.568A>C | RNA (SNP) | VAF 55/180 reads (31%) | called by muse, mutect2, varscan2
- CTSL3P | n.488G>A | RNA (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- ITIH5 | c.2032+746C>A | Intron (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99904898; called by muse, mutect2, varscan2
- SUGCT | c.1090-65372G>C | Intron (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100002439; called by muse, mutect2, varscan2
